Surgical pathology report (de-identified scan), TCGA case TCGA-WE-A8ZT, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Norfolk and Norwich Hospital, specimen TCGA-WE-A8ZT-06A (Metastatic).

[page 1 of 2]
Non Gynae Fine Needle Aspirate

Non Gynae Fine Needle Aspirate

ADDRESS FOR REPORT: Plastic Surgery
Copy To: Cancer Registry

CYTOPATHOLOGY REPORT

LAB No:

CASE HISTORY:

PT3b melanoma on mid upper back. Excised at
pregnant.

MACROSCOPIC:

3 air dried slides dated

MICROSCOPY:

Numerous malignant epithelioid cells, many of which contain intracytoplasmic pigment granules. Appearances are of metastatic melanoma. No significant lymphoid population is identified.

DIAGNOSIS:

RIGHT LEVEL VI LYMPH NODE FNA: METASTATIC MELANOMA

REPORTED BY:

. Consultant Histopathologist.

REPORT DATE:

X

Sample	(Tissue) Collected	Received
--------	--------------------	----------

Surgical Histology

Surgical Histology

ADDRESS FOR REPORT: PLASTICS
Copy To: Cancer Registry

HISTOPATHOLOGY REPORT

LAB No:

CASE HISTORY:

None provided

MACROSCOPIC:

- 1.Sentinel node left trapezius. Fatty tissue 4.5 x 2 x 1 cm containing a lymph node up to 1 cm.
- 2.Wider excision. Sutured disc 5 x 4.5 cm with brown nodule up to 1.2 cm centrally. 2A and 2B include deep margin. 2C includes closest circumferential margin.
- 3.Sentinel node 1 right axilla. 1.5 cm lymph node containing a 0.3 cm white nodule.

ICD. O-3
Melanoma NOS 8720/3
Site: lymph node, axilla CT7E
7/10 5/19/14

[page 2 of 2]
- 4.Sentinel node 2 right axilla. 0.5 cm lymph node with fat.
- 5.Sentinel node 3 right axilla. Two nodes larger 0.7 cm.
- 6.Sentinel node 1 left axilla. 2 cm lymph node.
- 7.External jugular vein plus node. Strip of fatty tissue up to 4 cm.
- 8.Level 2 right.
- 9.Right level 3.
- 10.Left level 4. Fatty tissue up to 5 cm.
- 11.Right level 5A. Fat up to 5 cm.
- 12.Right level 5B. Triangular piece of fatty tissue 9 x 6.5 x 2. At one edge is some black ink beneath which is half of a bisected lymph node up to 1 cm (12A). Its relation to the original surgical margin is not possible to determine.

MICROSCOPY:

1. Lymph node, negative for metastatic tumour
2. Granulation tissue and scarring: no tumour seen
3. Metastatic malignant melanoma, up to 3.8mm diameter, with extracapsular spread.
4. Metastatic malignant melanoma, up to 2.9mm diameter, without definite extracapsular spread.
5. Metastatic malignant melanoma, up to 0.9mm diameter, without extracapsular spread.
6. Bland capsular naevus cells present but no melanoma seen
7. One negative node
8. Sixteen negative nodes
9. Ten negative nodes
10. Five negative nodes
11. Three negative nodes
12. Metastatic malignant melanoma, 11.5mm diameter. Extracapsular tumour is present which extends to a diathermied margin, although how this relates to the true surgical margin is impossible to determine, due to the distortion from the (assumed) tissue banking sampling. The tumour is BRAF positive. Seven other nodes are negative

DIAGNOSIS:

SENTINEL LYMPH NODES, RIGHT AXILLA 1, 2, 3: METASTATIC MALIGNANT MELANOMA
RIGHT LEVEL V LYMPH NODE: METASTATIC MALIGNANT MELANOMA
LEFT TRAPEZIUS, LEFT AXILLA SENTINEL LYMPH NODES: NEGATIVE FOR TUMOUR

REPORTED BY:

Consultant Histopathologist.

REPORT DATE:

Source: NCI Genomic Data Commons file ecfcf39d-3833-45d7-92a0-8b395c3aad6e (TCGA-WE-A8ZT.25D3659C-B499-41FE-BE09-D79A76C843F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).